Somatic mutation profile of tumor specimen TARGET-10-PAPBVD-09A (aliquot TARGET-10-PAPBVD-09A-01D) from TARGET case TARGET-10-PAPBVD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (904 days).
Specimen TARGET-10-PAPBVD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41faa93b-dee4-4d02-893c-54110cc0b427.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBVD-10A (Blood Derived Normal), aliquot TARGET-10-PAPBVD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27a2d54b-be56-493b-afc7-c676a93c1f88

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as CM1512459; called by muse, mutect2, varscan2
- KDM4D | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV58635545; called by muse, mutect2
- MYLK | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60608980; called by muse, mutect2
- NCOA6 | c.5542G>T p.A1848S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.039); catalogued as COSV62866598; called by muse, mutect2
- NEDD9 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ZNF618 | c.2074C>A p.P692T (on ENST00000374126 / NM_001318042.2; = p.P599T on NM_133374.2) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- STPG2 | c.1107T>C p.H369= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as COSV99759773; called by muse, mutect2, varscan2
